TCGA case TCGA-V4-A9ET — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: Institut Curie. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5383fb57-69c2-4b34-af7f-c67208efb2b5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: France; Age at index: 57 years; Year of birth: 1954; Vital status: Dead; Days to death: 2,357 days (6.5 years); Year of death: 2018.

Diagnoses (1)
1. Mixed epithelioid and spindle cell melanoma: ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.30; Tissue or organ of origin: Choroid; Site of resection or biopsy: Choroid; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 57.8 years (21,113 days); Year of diagnosis: 2011; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4b; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T4b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,357 days (6.5 years); Sites of involvement: Eye, Choroid / Eye, Ciliary Body / Eye, Iris.
   Pathology details: Consistent pathology review: No; Epithelioid cell percent range: 31-60%; Extrascleral extension present: No; Measurement type: Echographic; Spindle cell percent range: 31-60%; Tumor depth measurement: 13.
   Pathology details: Measurement type: Pathologic; Tumor basal diameter: 17.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -12 days; Residual disease: R0; Treatment anatomic sites: Eye.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fotemustine; Days to treatment start: 21 days; Days to treatment end: 174 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fotemustine; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 148 days; Number of cycles: 5; Treatment dose: 200 mg; Reason treatment ended: Course of Therapy Completed.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Dacarbazine; Days to treatment start: 1,957 days (5.4 years); Days to treatment end: 2,094 days (5.7 years); Number of cycles: 3; Treatment dose: 1,600 mg; Treatment outcome: No Response; Reason treatment ended: Other.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Pembrolizumab; Treatment intent type: Salvage; Days to treatment start: 2,094 days (5.7 years); Days to treatment end: 2,262 days (6.2 years); Number of cycles: 8; Treatment dose: 202 mg; Treatment outcome: No Response; Reason treatment ended: Other.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (5 entries)
- Days to follow up: 872 days (2.4 years); Disease response: Tumor Free.
- Days to follow up: 963 days (2.6 years); Disease response: Tumor Free.
- Days to follow up: 1,362 days (3.7 years); Disease response: Tumor Free.
- Days to follow up: 1,926 days (5.3 years); Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,926 days (5.3 years).
- Days to follow up: 2,357 days (6.5 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive; Chromosome arm: p.
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 8.

Other clinical attributes
- Eye color: Blue.
- Timepoint category: Initial Diagnosis; Weight: 95 kg; Height: 177 cm; BMI: 30.3.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Melanoma.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-V4-A9ET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 30 mg.
  Slide TCGA-V4-A9ET-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-V4-A9ET-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-V4-A9ET-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology, Tumor tissue site list: Submitted tumor site: Ciliary body; Submitted tumor site: Iris.
- Primary pathology, Tumor morphology list, Tumor morphology 1: Histologic diagnosis: Spindle Cell.
- Primary pathology, Tumor morphology list, Tumor morphology 2: Histologic diagnosis: Epithelioid Cell.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 6p gain.
- Primary pathology: Tumor basal diameter mx: Pathologic Measurement; Tumor thickness measurement: Echographic Measurement.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,362 days; disease-specific survival: no event (censored), 1,362 days; progression-free interval: no event (censored), 1,362 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-V4-A9ET-01A-11D-A39V-01): tumor purity 1, ploidy 2.09, whole-genome doublings 0.

Additional fields from the TCGA clinical supplement workbook ExtendedFollowUp_clinicalSupplement.xlsx:
- abnormality: Gain 6p, 8q
- cancer type 1: cutaneous melanoma
- days to metastasis: 1926
- days to outcome: 2318
- days to pharm therapy imaging 1: 200
- days to pharm therapy imaging 3: 2250
- days to procedure 1: -12
- disease status at death: Evidence of Disease
- drug name 1: fotemustin
- drug name 2: deticene
- line of therapy 1: first
- m stage: M0
- morphologic subtype: spindle
- n stage: N0
- number cycles 1: 5
- number cycles 2: 3
- number cycles 3: 8
- outcome: Progressive Disease
- performance status scale: Karnofsky
- performance status score: 1
- pharm therapy dose units 1: mg
- pharm therapy dose units 2: mg
- pharm therapy dose units 3: mg
- pharm therapy evaluated by imaging 1: yes
- pharm therapy evaluated by imaging 3: yes
- pharm therapy imaging type 1: CT
- pharm therapy imaging type 3: MRI
- pharm therapy status 1: completed as planned
- pharm therapy status 2: treatment change
- pharm therapy status 3: treatment discontinued
- pharm therapy status reason 2: Lack of Response
- pharm therapy status reason 3: Lack of Response
- resection status 1: R0
- smoking status: smoker
- staging system: AJCC
- t stage: T4b
- test methodology: aCGH
- test result: intermediate risk
- unresectable 1: no
